Somatic mutation profile of tumor specimen TCGA-4Z-AA89-01A (aliquot TCGA-4Z-AA89-01A-11D-A391-08) from TCGA case TCGA-4Z-AA89, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 61.0 years (22,271 days).
Specimen TCGA-4Z-AA89-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b57fc43a-0a47-4aa9-bdf3-fd9b33a153d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4Z-AA89-10A (Blood Derived Normal), aliquot TCGA-4Z-AA89-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6ca5307-4a88-4c1e-b8f7-300f29a686b7

The open-access MAF lists 154 somatic variants for this specimen: 113 protein-altering or splice-affecting, 37 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 37, Nonsense Mutation 20, Splice Site 4, Intron 4, Frame Shift Del 2, Translation Start Site 1, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 11/22 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KDM6A | c.1663C>T p.Q555* | Nonsense Mutation (SNP) | VAF 28/30 reads (93%) | hotspot (GDC flag); catalogued as COSV65037942; called by muse, mutect2, varscan2
- MAP2K2 | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs727504370, CM086854, COSV53564551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 6/100 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1064793663, COSV55877982, COSV55886419, COSV56022812; ClinVar: pathogenic; called by muse, mutect2
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 44/104 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC2 | c.1372G>C p.E458Q | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.4); PolyPhen probably damaging (1); catalogued as COSV100966459, COSV64988011; called by muse, mutect2, varscan2
- ACADVL | c.914C>G p.S305* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99138469; called by muse, mutect2
- ACP3 | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs140885758, COSV60486803; called by muse, mutect2, varscan2
- AKAP6 | c.2880-2A>T p.X960_splice | Splice Site (SNP) | VAF 32/79 reads (41%) | catalogued as COSV55227503; called by muse, mutect2, varscan2
- ANK3 | c.9037G>C p.E3013Q | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV55075263; called by muse, mutect2, varscan2
- ARHGEF6 | c.1075C>G p.Q359E | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.542); catalogued as COSV51687106; called by muse, mutect2, varscan2
- ATMIN | c.2050C>T p.Q684* | Nonsense Mutation (SNP) | VAF 62/139 reads (45%) | catalogued as COSV100214607; called by muse, mutect2, varscan2
- ATMIN | c.2275C>G p.Q759E | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs778556195, COSV55147174; called by muse, mutect2, varscan2
- BAG6 | c.3202C>T p.Q1068* (on ENST00000676571; = p.Q1021* on NM_080702.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/85 reads (9%) | catalogued as COSV52992425, COSV99276915; called by muse, mutect2
- BAP1 | c.1251-1G>C p.X417_splice | Splice Site (SNP) | VAF 11/62 reads (18%) | catalogued as COSV56238622, COSV56242249; called by muse, mutect2, varscan2
- C1orf131 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/68 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV59642958; called by muse, mutect2, varscan2
- C1orf158 | c.351G>A p.W117* | Nonsense Mutation (SNP) | VAF 40/88 reads (45%) | catalogued as COSV99847288; called by muse, mutect2, varscan2
- CD274 | c.562_563insTTCA p.E188Vfs*18 | Frame Shift Ins (INS) | VAF 23/72 reads (32%) | catalogued as COSV67501656; called by mutect2, pindel, varscan2
- CFAP100 | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61504187; called by muse, mutect2, varscan2
- CHST9 | c.413G>C p.G138A | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as COSV52446130; called by muse, mutect2, varscan2
- CNBD1 | c.783G>C p.W261C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.213); catalogued as rs1334110990, COSV73074569; called by muse, mutect2, varscan2
- CPB1 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as rs760745745, COSV51576055; called by muse, mutect2, varscan2
- CPD | c.1927C>T p.Q643* | Nonsense Mutation (SNP) | VAF 11/97 reads (11%) | catalogued as COSV99075767; called by muse, mutect2, varscan2
- CSTL1 | c.255G>C p.K85N | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as COSV55678895; called by muse, mutect2, varscan2
- CYP26A1 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 13/201 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56419550; called by muse, mutect2
- DNAJB1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as rs768130288, COSV54317227, COSV54317299; called by muse, mutect2, varscan2
- DST | c.9949A>G p.I3317V | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs1481355717, COSV55033265; called by muse, mutect2, varscan2
- EDN3 | c.110C>G p.P37R | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.648); catalogued as COSV61109575; called by muse, mutect2, varscan2
- EGR4 | c.926C>T p.A309V (on ENST00000545030; = p.A206V on NM_001965.4) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1321611453; called by muse, mutect2
- EIF3D | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV53403926; called by muse, mutect2, varscan2
- ELAC1 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as rs551992289, COSV53997026; called by muse, mutect2, varscan2
- EPPK1 | c.4206C>A p.F1402L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV73262244; called by muse, mutect2
- FADD | c.107T>C p.L36P | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57229636; called by muse, mutect2, varscan2
- FAM193A | c.3719C>T p.S1240F (on ENST00000324666 / NM_001256666.1; = p.S1199F on NM_003704.3) | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV61197265; called by muse, mutect2, varscan2
- FBXL17 | c.1741G>C p.D581H | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62854696, COSV62858769; called by muse, mutect2, varscan2
- FRG1 | c.260-1del p.X87_splice | Splice Site (DEL) | VAF 4/28 reads (14%) | catalogued as rs1265231392; called by pindel, varscan2
- GCA | c.131C>A p.S44* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as COSV99280525; called by muse, mutect2, varscan2
- GSDMC | c.1273C>T p.Q425* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as COSV52697540; called by muse, mutect2
- GSTA3 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV52981253; called by muse, mutect2, varscan2
- GUCY2C | c.1057C>G p.H353D | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV53794163; called by muse, mutect2, varscan2
- HECW1 | c.3763C>T p.R1255C | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67825458, COSV67829709; called by muse, mutect2
- IGLV1-36 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.397); catalogued as rs546512166; called by muse, mutect2
- INSC | c.1129G>A p.V377I | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765115884, COSV101089722, COSV65409755; called by muse, mutect2, varscan2
- ITGA5 | c.3149G>C p.*1050Sext*10 | Nonstop Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as rs953624491, COSV99516607; called by muse, mutect2, varscan2
- KATNAL2 | c.1570C>G p.L524V (on ENST00000356157 / NM_001353899.1; = p.L452V on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); catalogued as COSV55306242; called by muse, mutect2, varscan2
- KDELR2 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.02); catalogued as COSV51727629; called by muse, mutect2, varscan2
- KDR | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV99817443; called by muse, mutect2
- KIF13A | c.5059G>A p.E1687K | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as COSV52461977; called by muse, mutect2, varscan2
- KRT33A | c.938A>T p.Q313L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV50372519; called by muse, mutect2, varscan2
- KRT78 | c.989C>G p.S330C | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs368480065, COSV58853090; called by muse, varscan2
- LAMA4 | c.1998A>T p.K666N (on ENST00000230538 / NM_001105206.3; = p.K659N on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.826); catalogued as COSV57903009; called by muse, mutect2, varscan2
- LRFN2 | c.2258C>T p.T753M | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760154787, COSV57826029; called by muse, mutect2, varscan2
- LRP6 | c.3395C>G p.S1132* | Nonsense Mutation (SNP) | VAF 13/109 reads (12%) | catalogued as COSV99743053; called by muse, mutect2, varscan2
- LRRC47 | c.1328A>C p.D443A | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV65563381; called by muse, mutect2
- LRRC66 | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV58635987, COSV58636859; called by muse, mutect2, varscan2
- MAP3K9 | c.3081G>C p.E1027D (on ENST00000554752 / NM_001284230.1; = p.E1041D on NM_033141.4) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV67122529; called by muse, mutect2
- MLXIP | c.1466C>G p.S489C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV59837308; called by muse, mutect2, varscan2
- MSRB3 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV57595651; called by muse, varscan2
- MUC16 | c.25544C>T p.S8515L | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.028); catalogued as rs768891925, COSV67484360; called by muse, mutect2, varscan2
- MYCBP2 | c.6322G>A p.E2108K (on ENST00000357337; = p.E2146K on NM_015057.5) | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV62033884; called by muse, mutect2, varscan2
- MYH10 | c.3626C>T p.S1209L | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.309); catalogued as COSV52607989; called by muse, mutect2, varscan2
- MYRF | c.822G>C p.M274I (on ENST00000278836 / NM_001127392.3; = p.M265I on NM_013279.4) | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.039); catalogued as COSV53892525; called by muse, mutect2, varscan2
- NCAPD2 | c.732C>G p.I244M | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV59701726; called by muse, mutect2, varscan2
- NOP56 | c.1484G>C p.G495A | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.433); catalogued as COSV100249911, COSV61391105; called by muse, mutect2, varscan2
- NOP56 | c.1671G>C p.K557N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.117); catalogued as COSV100250065; called by muse, mutect2
- NSRP1 | c.668C>G p.S223* | Nonsense Mutation (SNP) | VAF 25/73 reads (34%) | catalogued as COSV99898340; called by muse, mutect2, varscan2
- OR6C1 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as COSV65573067, COSV65573189; called by muse, mutect2, varscan2
- OR7C1 | c.46G>T p.G16* | Nonsense Mutation (SNP) | VAF 56/160 reads (35%) | catalogued as rs1327028351, COSV99934863; called by muse, mutect2, varscan2
- OVCH2 | c.289A>T p.R97* | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | catalogued as COSV101491885; called by muse, mutect2, varscan2
- PHACTR2 | c.1685G>C p.R562T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV59854198, COSV59856744; called by muse, mutect2, varscan2
- PIWIL1 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 13/87 reads (15%) | catalogued as rs369068461; called by muse, mutect2, varscan2
- PLB1 | c.2168C>T p.S723F | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59833068; called by muse, mutect2, varscan2
- POLR2B | c.3053A>G p.Y1018C | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.989); catalogued as rs1420625581, COSV58902174; called by muse, mutect2, varscan2
- POLR3A | c.3355G>T p.E1119* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100965628; called by muse, mutect2, varscan2
- PREX2 | c.2852C>G p.S951* | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | catalogued as COSV99906691; called by muse, mutect2, varscan2
- PSMA8 | c.202G>C p.D68H | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57604373; called by muse, mutect2, varscan2
- PTPN3 | c.290-2A>T p.X97_splice | Splice Site (SNP) | VAF 63/76 reads (83%) | catalogued as COSV52709705; called by muse, mutect2, varscan2
- PTPRU | c.612G>C p.Q204H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV100112496; called by mutect2, varscan2
- RAI1 | c.1493C>G p.S498* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99883405; called by muse, mutect2
- RAPGEF3 | c.322C>A p.L108M (on ENST00000389212; = p.L66M on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.538); catalogued as COSV99406217; called by mutect2, varscan2
- RELN | c.100T>C p.S34P | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.441); catalogued as COSV59004765; called by muse, mutect2, varscan2
- RGS22 | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV62662475; called by muse, mutect2, varscan2
- RHOBTB3 | c.1646C>G p.S549* | Nonsense Mutation (SNP) | VAF 9/75 reads (12%) | catalogued as COSV101183178; called by muse, mutect2, varscan2
- RPS12 | c.182A>G p.Y61C | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.229); catalogued as COSV57767674; called by muse, mutect2, varscan2
- RPS6KC1 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as COSV100874007, COSV65301993; called by muse, mutect2, varscan2
- RXFP1 | c.958G>C p.E320Q | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.022); catalogued as COSV57054611; called by muse, mutect2
- RYR2 | c.8767T>A p.Y2923N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV63705496; called by muse, mutect2, varscan2
- SMC4 | c.41G>C p.R14T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.017); catalogued as COSV100424654; called by muse, mutect2
- SNED1 | c.3065C>A p.S1022* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100122561; called by muse, mutect2, varscan2
- SNRNP48 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.437); catalogued as rs1368244791, COSV60940458; called by muse, mutect2, varscan2
- SPNS1 | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV57956144; called by muse, varscan2
- ST8SIA2 | c.583G>C p.D195H | Missense Mutation (SNP) | VAF 11/70 reads (16%) | PolyPhen probably damaging (0.982); catalogued as COSV51571968, COSV99184339; called by muse, mutect2, varscan2
- STAG2 | c.3113G>A p.W1038* | Nonsense Mutation (SNP) | VAF 40/48 reads (83%) | catalogued as COSV54362034; called by muse, mutect2, varscan2
- STAU1 | c.210C>G p.S70R | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV61461900; called by muse, mutect2
- STEAP1 | c.119G>C p.R40T | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1437275150, COSV51881816; called by muse, mutect2, varscan2
- TLE4 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 73/95 reads (77%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as COSV54629902; called by muse, mutect2, varscan2
- TNFRSF1A | c.520C>G p.L174V | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as COSV50608355; called by muse, mutect2
- TRRAP | c.3473T>G p.L1158R | Missense Mutation (SNP) | VAF 72/177 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV62851843; called by muse, mutect2, varscan2
- TTC29 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs201549008, COSV100283223; called by muse, mutect2, varscan2
- TTC31 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as COSV99282121; called by muse, mutect2
- TTF1 | c.660G>C p.K220N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); catalogued as COSV57506613; called by muse, mutect2, varscan2
- UBE2B | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.836); catalogued as COSV54760060, COSV54760907; called by muse, mutect2, varscan2
- ZBTB17 | c.2263C>G p.Q755E | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV65271282; called by muse, mutect2
- ZCCHC8 | c.739A>T p.N247Y | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV60319490; called by muse, mutect2, varscan2
- ZFYVE16 | c.871G>C p.E291Q | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.08); catalogued as COSV62016997; called by muse, mutect2, varscan2
- ZFYVE16 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV62017005; called by muse, mutect2, varscan2
- ZMYM6 | c.894C>G p.F298L | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV100451585; called by muse, mutect2
- ZNF695 | c.785A>T p.H262L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV60587095; called by muse, mutect2, varscan2
- ZZZ3 | c.1423C>G p.Q475E | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV66234843; called by muse, mutect2, varscan2
- GPR179 | c.3487A>T p.S1163C (on ENST00000621958; = p.S1162C on NM_001004334.4) | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR6C65 | c.305del p.L102* | Frame Shift Del (DEL) | VAF 46/124 reads (37%) | called by mutect2, varscan2
- WASHC2A | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ZBTB7B | c.1066del p.H356Mfs*10 (on ENST00000292176; = p.H390Mfs*10 on NM_001252406.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/75 reads (29%) | called by mutect2, pindel, varscan2
- ABCG1 | c.1701C>T p.F567= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs1311072834, COSV59207914; called by muse, mutect2, varscan2
- ADAMTS17 | c.933G>A p.Q311= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1432311670, COSV51490155; called by muse, mutect2, varscan2
- ALG1 | c.699C>G p.L233= | Silent (SNP) | VAF 29/106 reads (27%) | catalogued as COSV52158899; called by muse, mutect2, varscan2
- BCR | c.1506C>G p.V502= | Silent (SNP) | VAF 4/74 reads (5%) | catalogued as COSV100006378; called by muse, mutect2
- DNAJB5 | c.87G>A p.L29= | Silent (SNP) | VAF 20/115 reads (17%) | catalogued as COSV56627094; called by muse, mutect2, varscan2
- DPYD | c.303C>T p.I101= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as COSV60082021; called by muse, mutect2, varscan2
- DUOXA1 | c.588G>A p.V196= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as COSV50994437; called by muse, mutect2, varscan2
- EMILIN2 | c.1104C>T p.L368= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs776824246, COSV54426356; called by muse, mutect2, varscan2
- EPPK1 | c.5034C>T p.I1678= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as rs782182977, COSV101599819; called by muse, mutect2, varscan2
- FGF23 | c.366C>T p.N122= | Silent (SNP) | VAF 43/101 reads (43%) | catalogued as rs145147639; called by muse, mutect2, varscan2
- GCKR | c.1179G>C p.L393= | Silent (SNP) | VAF 35/124 reads (28%) | catalogued as COSV53110423; called by muse, mutect2, varscan2
- GPR155 | c.516G>A p.V172= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as rs907208647, COSV55041072; called by muse, mutect2, varscan2
- IGDCC3 | c.2091G>A p.A697= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs748924376, COSV60079361; called by muse, mutect2, varscan2
- IL18R1 | c.1069C>T p.L357= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV52126517; called by muse, mutect2, varscan2
- ITPRID1 | c.2139C>T p.S713= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV60080636; called by muse, mutect2, varscan2
- JAG1 | c.1464C>A p.I488= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV54761351; called by muse, mutect2, varscan2
- KLK1 | c.573G>A p.Q191= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV56827995; called by muse, mutect2, varscan2
- LAMA3 | c.2751G>A p.G917= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as rs1377922093, COSV58076187; called by muse, mutect2, varscan2
- MAVS | c.1323C>T p.I441= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV63927389; called by muse, mutect2
- MMP27 | c.36A>T p.I12= | Silent (SNP) | VAF 38/80 reads (48%) | catalogued as COSV52782190; called by muse, mutect2, varscan2
- MROH2B | c.3105G>A p.L1035= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV68187909; called by muse, mutect2, varscan2
- MUC17 | c.12360G>A p.K4120= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV60286119, COSV60286303, COSV60299259; called by muse, mutect2, varscan2
- MYO10 | c.4236G>A p.L1412= | Silent (SNP) | VAF 53/136 reads (39%) | catalogued as COSV57027423; called by muse, mutect2, varscan2
- OR4P4 | c.177C>T p.F59= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV58923241; called by muse, mutect2, varscan2
- PCNX3 | c.195C>T p.L65= | Silent (SNP) | VAF 9/112 reads (8%) | catalogued as rs764521062, COSV58421235; called by muse, mutect2
- PLSCR2 | c.837C>T p.A279= (on ENST00000497985 / NM_001199978.1; = p.A206= on NM_020359.2) | Silent (SNP) | VAF 48/121 reads (40%) | catalogued as rs777863729, COSV60863551; called by muse, mutect2, varscan2
- PPP4C | c.837C>A p.L279= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV54222913; called by muse, mutect2, varscan2
- PSD2 | c.612G>A p.A204= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs115268774, COSV51207171; called by mutect2, varscan2
- RAPGEF4 | c.1857C>G p.L619= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV51407890; called by muse, mutect2, varscan2
- SCRIB | c.1548C>T p.A516= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs538041646, COSV57591890; called by muse, mutect2, varscan2
- SUGP2 | c.2859C>T p.I953= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs998742500, COSV58263292; called by muse, mutect2, varscan2
- TMEM26 | c.126C>T p.L42= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as rs1246934389, COSV67493113; called by muse, mutect2, varscan2
- TWF2 | c.291G>C p.L97= | Silent (SNP) | VAF 12/156 reads (8%) | catalogued as COSV100564507; called by muse, mutect2
- USP47 | c.2409G>A p.Q803= (on ENST00000399455 / NM_001372095.1; = p.Q715= on NM_017944.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 18/150 reads (12%) | catalogued as COSV60466786, COSV60467178; called by muse, varscan2
- VWA8 | c.3807C>T p.L1269= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as COSV64999328; called by muse, varscan2
- ZKSCAN2 | c.2175G>T p.P725= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as COSV100048197, COSV60158278; called by muse, mutect2, varscan2
- ZNF585B | c.411G>A p.K137= | Silent (SNP) | VAF 13/115 reads (11%) | catalogued as COSV57214464, COSV57216558; called by muse, mutect2, varscan2
- FMN1 | c.2044-1772C>G | Intron (SNP) | VAF 12/90 reads (13%) | catalogued as COSV57919430; called by muse, mutect2, varscan2
- GCNT2 | c.925+26647C>T | Intron (SNP) | VAF 9/105 reads (9%) | catalogued as COSV60235225; called by muse, mutect2
- NALCN | c.2193-5321G>A | Intron (SNP) | VAF 8/25 reads (32%) | catalogued as rs1285398807, COSV51920739; called by muse, mutect2, varscan2
- RPL3 | c.4-491A>T | Intron (SNP) | VAF 33/67 reads (49%) | catalogued as COSV53366310; called by muse, mutect2, varscan2
